Somatic mutation profile of tumor specimen TCGA-J9-A52E-01A (aliquot TCGA-J9-A52E-01A-11D-A26M-08) from TCGA case TCGA-J9-A52E, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.0 years (23,741 days).
Specimen TCGA-J9-A52E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ab112bd-fe91-4a55-904a-554785cdb522.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J9-A52E-10A (Blood Derived Normal), aliquot TCGA-J9-A52E-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0b16ede-528a-4fa7-8651-4fdbd07dfef7

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 19, Silent 8, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B2 | c.1490C>T p.T497M (on ENST00000672630; = p.T464M on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs754483178, COSV59246819; called by muse, mutect2, varscan2
- BMX | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs1029888196, COSV53023604; called by muse, mutect2, varscan2
- CTU2 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.917); catalogued as rs374694184; called by muse, mutect2, varscan2
- DAPK1 | c.2215A>T p.K739* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV63791661; called by muse, mutect2, varscan2
- MAFF | c.19T>C p.S7P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs377667070; called by muse, mutect2, varscan2
- MC3R | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54764875; called by muse, mutect2, varscan2
- MUC16 | c.9547G>T p.A3183S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs371846589, COSV67490444; called by muse, mutect2, varscan2
- NLRP4 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs368338379; called by muse, mutect2, varscan2
- PPP4R1 | c.119C>T p.S40L (on ENST00000400556 / NM_001042388.3; = p.S23L on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1225739264, COSV53283110, COSV53284359, COSV99553801; called by muse, mutect2, varscan2
- SI | c.3596G>T p.G1199V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52299114; called by muse, mutect2
- SRPX2 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.897); catalogued as rs761966457, COSV52171387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYCP2 | c.3767C>A p.S1256Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100698004, COSV62772177; called by muse, mutect2, varscan2
- TBC1D2 | c.1465G>C p.E489Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV59788496; called by muse, mutect2, varscan2
- TENM3 | c.5983C>A p.Q1995K | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.258); catalogued as COSV69318118; called by muse, mutect2, varscan2
- THAP12 | c.1795C>T p.L599F | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV52612885; called by muse, mutect2, varscan2
- TNN | c.313G>T p.V105F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV53434511, COSV53435957; called by muse, mutect2, varscan2
- TRAPPC6B | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs538309490, COSV57528532; called by muse, mutect2, varscan2
- TREH | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1423018299, COSV50626602; called by muse, mutect2, varscan2
- TRRAP | c.11054T>G p.V3685G (on ENST00000359863 / NM_001244580.1; = p.V3656G on NM_003496.3) | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV62816737; called by muse, mutect2, varscan2
- ZZEF1 | c.3605G>T p.W1202L | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67560049; called by muse, mutect2, varscan2
- CABCOCO1 | c.624C>G p.A208= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV57593398, COSV57595856; called by muse, mutect2, varscan2
- CADM3 | c.771C>T p.R257= (on ENST00000368125 / NM_001127173.3; = p.R291= on NM_021189.5) | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs373766355; called by muse, mutect2, varscan2
- CEACAM16 | c.1011C>T p.T337= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs764689326, COSV69188284; called by muse, mutect2, varscan2
- GPR26 | c.465G>A p.S155= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV52933836; called by muse, mutect2, varscan2
- H3C10 | c.54C>A p.R18= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as COSV60798717; called by muse, mutect2, varscan2
- IWS1 | c.723G>A p.E241= | Silent (SNP) | VAF 36/154 reads (23%) | catalogued as rs1277234559, COSV54871552; called by muse, mutect2, varscan2
- TAGLN3 | c.336G>A p.Q112= | Silent (SNP) | VAF 12/101 reads (12%) | catalogued as rs754085225, COSV56329384; called by muse, mutect2, varscan2
- TMEM140 | c.39G>A p.L13= | Silent (SNP) | VAF 16/155 reads (10%) | catalogued as COSV51967528; called by muse, mutect2, varscan2
